Surgical pathology report (de-identified scan), TCGA case TCGA-DV-A4VX, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-A4VX-01A (Primary Tumor).

[page 1 of 4]
MEDICAL RECORD**Surgical Pathology Report**

**Surgical Pathology Report****PATIENT:****ACCOUNT#:****DOB:****AGE:****SEX: M****ATTENDING:****REQUESTING:****CONTACT NO: (MD) -****COPIES TO:****MRN:****RECEIVED DATE:****PROCEDURE DATE:****SIGN-OUT DATE:****LOCATION:****ROOM:****DIAGNOSIS:**

1. Kidney and adrenal gland, right (radical nephrectomy and adrenalectomy): Renal cell carcinoma, clear cell type, Fuhrman nuclear grade IV; tumor involves the renal vein; prominent vascular invasion is present; tumor penetrates through the capsule with involvement of perinephric tissue; tumor present in the lymphatic spaces surrounding the ureteral margin; arterial margin free of tumor; hilar lymph nodes free of tumor (0/2); adrenal gland free of tumor; inked margin of resection free of tumor.

-- 2. Lymph node, intraaortic cava (lesion): An atypical cell is present in one of four lymph nodes.

} 3. Lymph node, pericaval (excision): Reactive lymph nodes, no tumor seen (0/19).

NOTE:**Kidney Nephrectomy Summary Table Macroscopic****Specimen Type:** Radical nephrectomy and adrenalectomy**Laterality:** Right**Tumor Size:** 11.5 x 7.4 cm**Focality:** Unifocal**Macro Extent of Tumor:** Tumor extends into perinephric tissue**Microscopic****Histologic Type:** Renal cell carcinoma, clear cell type.**Histologic Grade:** Fuhrman nuclear grade IV

ICD-O-3

carcinoma, clear cell 8310/3

Site: kidney, NOS C64.9

fw
10/24/12

Patient Identification

Surgical Pathology Report

File in

[page 2 of 4]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name:

Accession No.:

MRN:

Extent of Invasion

Primary Tumor(pT): pT3b

Regional Lymph Nodes(pN): An atypical cell present in one of the intraaortic lymph nodes.

Distant Metastasis(pM): pMx

Margins: Free of tumor

CLINICAL INFORMATION: Allocate Order to Protocol:
right renal mass with lung metastases and retroperitoneal
lymphadenopathy Specimen Taken For Protocol: 01 - Yes

Brief Clinical History: huge

PROCEDURE: Pre-Operative Diagnosis: right renal mass Post-Operative Diagnosis:
same Operative Findings: large right renal mass with vena cava tumor
thrombus, bulky retroperitoneal lymphadenopathy

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT
2. LYMPH NODES, Interaortocaval
3. LYMPH NODES, Paracaval

GROSS DESCRIPTION:

1. Received fresh OR labeled with the patient's name, medical record number, and "right kidney and adrenal gland" is a radical nephrectomy specimen measuring 19 x 16 x 9.5 cm overall. There is a tumor thrombus protruding from the renal vein measuring 3 x 2 x 1 cm. The kidney is inked and bivalved to reveal a tumor measuring 11.5 x 7.4 cm with friable, red/brown, variegated, cut surface. The tumor is replacing most of the renal parenchyma. Fragments of tumor measuring 3.5 x 3.5 x 2.0 cm in aggregate were procured for ab, approximately 6.5 x 5 x 2.4 cm tumor and tumor thrombi measuring 2 x 2 x 1 cm were procured for The procurement was performed by on Received in Surgical Pathology, the specimen is consistent with the above description. Grossly, the tumor is largely necrotic, and does not invade through the Gerota's fascia, but the renal capsule is difficult to strip. Two hilar lymph nodes are identified measuring up to 0.7 cm in largest dimension. The adrenal gland is identified measuring 7 x 4 x 0.3 cm. Grossly, it is not involved by the tumor. Representative sections are submitted in white cassettes labeled 1A to 1Q for serial sectioning. The cassettes are summarized as follows:

1A: Artery and ureteral margins
1B: Renal vein thrombus
1C: Tumor thrombus in renal vein
1D-1I: Tumor with margins
1J-1P: Representative sections from the tumor
1Q: Lymph node (2)
1R: Tumor with margin near the adrenal gland
1S, 1T, 1U: Representative sections from the adrenal gland

Patient Identification	Surgical Pathology Report
------------------------	---------------------------

[page 3 of 4]
MEDICAL RECORD	Surgical Pathology Report
-----------------------	----------------------------------

Name:

Accession No.:

MRN:

Additional sections were later submitted in white cassettes labeled 1V-1Z for serial sectioning. The cassettes are summarized as follows:

- 1V-1Z: Tumor with margins.
- 1AA: Proximal end of a possible ureter
- 1BB: Distal end of the possible ureter
- 1CC: Venous thrombi cross-section
- 1DD: A tubular structure near the ureter, proximal
- 1EE: A tubular structure near the ureter, distal

2. "Intraaortic caval nodes". The specimen consists of a yellow/brown fibroadipose tissue measuring 5 x 2.5 x 0.6 cm. The specimen is bisected. Three possible lymph nodes are identified with the largest one measuring 2.5 cm in largest dimension. The lymph nodes are entirely submitted in white cassettes labeled 2A-2D for serial sectioning. The cassettes are summarized as follows:

- 2A: One lymph node
- 2B: One lymph node bisected
- 2C and 2D: One lymph node bisected

3. "Pericaval lymph node with stitch is cephalad". The specimen consists of two yellow/brown tissue fragments: One measures 7.5 x 4 x 1.5 cm, the other one measures 2 x 1 x 0.3 cm. The specimen is dissected and 17 possible lymph nodes are identified. The lymph nodes are entirely submitted in white cassettes labeled 3A-3H for serial sectioning. The cassettes are summarized as follows:

- 3A: Three lymph nodes
- 3B: One lymph node
- 3C: Three lymph nodes
- 3D: One lymph node
- 3E: Three lymph nodes
- 3F: One lymph node bisected
- 3G: Three lymph nodes
- 3H: Two lymph nodes

No consultants

Patient Identification

Surgical Pathology Report

[page 4 of 4]
MEDICAL RECORD	Surgical Pathology Report
----------------	---------------------------

Name: _____
MRN: _____

Accession No.: _____

Patient Identification

Surgical Pathology Report

Source: NCI Genomic Data Commons file 0265ce65-9f54-4ba7-b1c4-3974f98d4e3c (TCGA-DV-A4VX.E56FC671-66B2-485C-9D80-BFCD6A968017.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).